Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5589, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5589-01A (Primary Tumor).

TCGA-CW-5589

Surgical Pathology

TISSUE DESCRIPTION:

Tissue from left kidney (10.80 grams, 3.3 x 3.0 x 2.3 cm).

DIAGNOSIS:

Kidney, left, partial nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forms a 2.8 x 2.2 x 2.0 cm mass located in the upper pole. The tumor is confined to the kidney. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent.

Source: NCI Genomic Data Commons file 8571a98e-8e15-4485-8a7f-0fa573a3a1ef (TCGA-CW-5589.21B34DA2-1C07-4BB0-BC99-B21D6F9EBC35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).